Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2689, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2689-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Sigmoid colon and rectum
- B. Right tube and ovary
- C. Left tube and ovary

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectal cancer

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "sigmoid colon" is a 22 cm. long portion of colon. The specimen is opened at both ends with proximal end inked blue and distal inked black. The serosa is pink-tan smooth and glistening and the specimen shows retroperitoneal reflection located 4 cm. from the distal margin. The specimen is opened to show a pink-tan smooth glistening mucosa with a circumference of 4.5 cm. at the proximal margin and 9 cm. at the distal margin. There is a 5 x 4.7 x 1.5 cm. exophytic mass which is located 2.3 cm. from the distal margin. The cut surface shows invasion into the muscularis propria; however, no discrete invasion into the fat is grossly identified. This comes within 3 cm. of the radial margin. No other discrete gross lesions are identified. Lymph nodes are grossly identified in the fat. Representative sections of the specimen will be submitted following further fixation. [REDACTED]

BLOCK SUMMARY: 1 - representative luminal margin; 2-10 - whole lymph nodes; 11 - one possible lymph node sectioned. [REDACTED]

B. Received fresh labeled "right tube and ovary" is a 3.5 x 1.8 x 1.3 cm. cerebriiform tan-pink-gold ovary and associated, fimbriated 3.9 cm. pink-purple fallopian tube segment. The ovarian stroma is tan-pink with identifiable corpora lutea and corpora albicantia. In addition, there are a few smooth-lined serous fluid-filled cysts measuring up to 0.7 cm. The fallopian tube segment averages 0.5 cm. in diameter with a pinpoint stellate lumen on sectioning. Representative sections are submitted in three blocks

GROSS DESCRIPTION

as labeled. RS-3

BLOCK SUMMARY: 1 and 2 - ovary; 3 - fallopian tube.

[page 2 of 2]
[REDACTED]

C. Received fresh labeled "left tube and ovary" is a 4.6 x 2.2 x 1.4 cm. cerebriiform tan-pink-gold ovary and associated, fimbriated 3.7 cm. pink-purple fallopian tube segment. The ovarian stroma is pale tan-pink with identifiable corpora lutea and corpora albicantia. In addition, there are a few smooth-lined serous fluid-filled cysts measuring up to 1 cm. The fallopian tube segment averages 0.5 cm. in diameter with a pinpoint stellate lumen on sectioning. Representative sections are submitted in two blocks. RS-2 [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A.
Histologic type: Infiltrating adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): The tumor extends minimally into pericolic fat, pT3a/b
Proximal margin: Negative for tumor
Distal margin: Negative for tumor
Circumferential (radial) margin: Negative for tumor
Distance of tumor from closest margin: 2.3 cm from distal margin
Vascular invasion: Not detected
Regional lymph nodes (pN): Thirty-two lymph nodes are found, six of which contain metastatic adenocarcinoma, 6/32, pN2.
Non-lymph node pericolic tumor: Negative
Distant metastasis (pM): Cannot be assessed.

B, C. Microscopic examination performed.

MICROSCOPIC DESCRIPTION

5, 3x2

DIAGNOSIS

- A. Sigmoid colon and rectum, segmental resection - Moderately differentiated adenocarcinoma extending into pericolic fat. All margins are negative for tumor. Metastatic adenocarcinoma is present in six of thirty-two regional lymph nodes, 6/32.
- B. Right tube and ovary, right salpingo-oophorectomy - Ovary and fallopian tube, no significant pathology.
- C. Left fallopian tube and ovary, left salpingo-oophorectomy - Fallopian tube and ovary, no significant pathology.
- [REDACTED]

Source: NCI Genomic Data Commons file 4bcb88ce-7d87-45f1-bfc9-9db8385bb560 (TCGA-AF-2689.235CDE69-C494-4EC6-9862-1A7F367EEA40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).